Gene-level copy-number profile of tumor specimen TCGA-13-0723-01A from TCGA case TCGA-13-0723, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 63.2 years (23,094 days).
Specimen TCGA-13-0723-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.e4726939-32a7-4ecf-bcee-420817d9d234.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-0723-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0451f333-73c0-4615-af63-5aa8183840ac

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 3,049; copy number 2: 20,944; copy number 3: 17,677; copy number 4: 15,418; copy number 5: 1,159; copy number 6: 547; copy number 7: 131; copy number 8: 61; copy number 9: 5; copy number 10: 228; copy number 11: 212; copy number 13: 109; copy number 14: 81; copy number 18: 3; copy number 30: 138; copy number 36: 46.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-13-0723-01): tumor purity 0.69, ploidy 3.1, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,720 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,083,522–248,919,946, 45 genes, copy number 5: OR2T32P, OR2L13, OR2M1P, OR2M5, OR2M2, OR2M3, OR2M4, OR2T33, OR2T12, OR2M7, OR14C36, OR2T4, OR2T6, OR2T1, OR2T7, OR2T2, OR2T3, AC138089.1, OR2T5, OR2AS2P, OR2G6, AC098483.1, OR2AS1P, OR2T29, OR2T34, OR2T10, Y_RNA, AC098483.2, OR2T11, OR2T35, OR2T27, CR589904.2, OR14I1, LYPD9P, CR589904.1, AHCYP8, LYPD8, DPY19L4P1, SH3BP5L, MIR3124, ZNF672, ZNF692, AL672291.1, PGBD2, RNU6-1205P.
- chr2:28,448,167–29,189,643, 20 genes, copy number 5: AC104695.1, PLB1, SNRPGP7, AC074011.1, RNA5SP89, AC092164.1, PPP1CB, SPDYA, AC097724.1, TRMT61B, WDR43, SNORD92, SNORD53, Y_RNA, SNORD53B, TOGARAM2, Y_RNA, PCARE, AC105398.1, CLIP4.
- chr2:29,319,554–29,352,214, 1 gene, copy number 5 (within-gene range 3–5): AC074096.1.
- chr2:94,725,674–95,835,003, 67 genes, copy number 5 (broad region; genes not listed).
- chr3:104,063,039–120,908,093, 247 genes, copy number 9–18 (broad region; genes not listed).
- chr3:120,924,612–120,925,158, 1 gene, copy number 11: AC072026.1.
- chr5:58,198–50,970,187, 720 genes, copy number 5–6 (broad region; genes not listed).
- chr7:34,346,512–39,493,095, 100 genes, copy number 7 (broad region; genes not listed).
- chr7:41,960,949–42,264,100, 2 genes, copy number 6 (within-gene range 3–6): GLI3, HMGN2P30.
- chr8:28,890,395–31,390,805, 62 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr8:41,032,892–43,674,591, 81 genes, copy number 6 (broad region; genes not listed).
- chr8:105,546,089–106,060,524, 1 gene, copy number 5 (within-gene range 4–5): ZFPM2-AS1.
- chr8:105,737,280–108,443,496, 25 genes, copy number 5 (within-gene range 3–5): RPL12P24, AC090802.1, Y_RNA, SLC16A14P1, AC027031.1, AC027031.2, OXR1, AC090579.1, TAGLN2P1, RNU7-84P, ABRA, AP003789.1, AP000428.2, HMGB1P46, AP000428.1, ANGPT1, AC091010.1, PGAM1P13, AC025508.1, RNA5SP275, RSPO2, NRBF2P4, AURKBP1, EIF3E, AC087620.1.
- chr8:119,832,875–120,373,573, 9 genes, copy number 6 (within-gene range 4–6): AP005717.2, DSCC1, AC021945.1, RN7SL396P, AP005717.1, DEPTOR, RNA5SP277, AC091563.1, COL14A1.
- chr8:126,504,763–129,683,770, 34 genes, copy number 6–7 (within-gene range 4–7): RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824, CCDC26.
- chr8:129,484,057–133,134,903, 41 genes, copy number 5–8 (within-gene range 2–8): MIR3686, AC103718.1, MTRF1LP2, GSDMC, AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194, ASAP1, RNU6-1255P, ASAP1-IT2, AC103725.1, AC009682.1, AC139019.1, AC090987.1, ADCY8, AC103726.1, AC103726.2, AC087341.1, AC104257.1, SNORA72, AC060788.1, EFR3A, OC90, AC100868.1, HHLA1, KCNQ3, HPYR1, LRRC6, TMEM71, AF228727.1, PHF20L1, AF230666.2, AF230666.1, TG, AF305872.1.
- chr8:133,046,481–133,046,581, 1 gene, copy number 5: MIR7848.
- chr9:71,589,601–73,080,442, 24 genes, copy number 5: RPL35AP21, CEMIP2, AL671309.1, ABHD17B, Y_RNA, C9orf85, HSPB1P1, C9orf57, AL583829.1, BTF3P4, GDA, AL135924.2, AL135924.1, RNA5SP285, LINC01504, ZFAND5, AL445646.1, AL596448.1, TMC1, RPS20P24, RPS27AP15, LINC01474, ALDH1A1, CYP1D1P.
- chr11:74,397,549–79,441,030, 138 genes, copy number 30 (within-gene range 1–30) (broad region; genes not listed).
- chr11:85,336,075–91,383,289, 147 genes, copy number 10–13 (broad region; genes not listed).
- chr14:77,041,064–77,259,495, 11 genes, copy number 10: LINC02288, AC007686.2, LINC02289, AC007686.5, CIPC, AC007375.2, TMEM63C, ZDHHC22, AC007375.3, FAM204DP, AC007375.1.
- chr14:99,645,110–100,144,236, 10 genes, copy number 5 (within-gene range 2–5): HHIPL1, CYP46A1, AL160313.2, EML1, RNU1-47P, VDAC3P1, EVL, AL133368.1, AL133368.2, AL157912.1.
- chr18:47,390–2,049,510, 46 genes, copy number 36 (within-gene range 2–36): TUBB8B, AP001005.3, IL9RP4, AP001005.2, ROCK1P1, MIR8078, USP14, THOC1, AP000845.1, AP000915.1, COLEC12, AP000915.2, LINC01925, CETN1, RN7SKP146, CLUL1, AP001178.4, TYMSOS, AP001178.3, AP001178.1, TYMS, ENOSF1, AP001178.2, YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1, AP000894.1, AP000894.3, AP000894.2, ADCYAP1, LINC01904, AP005328.1, AP000829.1, SLC25A3P3, COX6CP3, LINC00470, RN7SKP72, AP005119.1, AP005119.2, AP005262.1, AC019183.1, AP005057.1.
- chr19:28,435,388–36,998,700, 289 genes, copy number 6–14 (broad region; genes not listed).
- chr19:37,024,886–37,025,254, 1 gene, copy number 6: AC010632.3.
- chr20:47,160,838–64,313,132, 414 genes, copy number 5–6 (broad region; genes not listed).
- chr21:43,865,223–46,665,124, 129 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr22:44,102,779–45,845,307, 41 genes, copy number 5 (within-gene range 3–5): AL033543.1, AL031595.3, PARVG, AL031595.1, AL031595.2, SHISAL1, Z85994.1, Z85994.2, LINC01656, MRPS18CP6, AL023973.1, RTL6, KRT18P23, LINC00207, LINC00229, ANP32BP2, PRR5, PRR5-ARHGAP8, ARHGAP8, PHF21B, Z83838.1, AL079301.1, NUP50-DT, Z82243.1, NUP50, AL008718.3, KIAA0930, MIR1249, AL008718.2, AL008718.1, UPK3A, FAM118A, SMC1B, RIBC2, AL021391.1, FBLN1, LINC01589, RNU6-1161P, Z95331.1, ATXN10, MIR4762.
- chr22:46,576,012–48,023,004, 13 genes, copy number 5 (within-gene range 1–5): GRAMD4, CERK, AL118516.1, TBC1D22A, TBC1D22A-AS1, FP325331.1, Z83836.1, Z82186.1, LINC01644, LINC00898, AL117329.1, AL117329.2, FP325330.3.

Autosomal genes at a single copy (total copy number 1): 2,627. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
